Somatic mutation profile of tumor specimen 0DUIXB from CCDI case PBCIZF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.8 years (5,773 days).
Specimen 0DUIXB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61f5a2fc-f74d-4738-af1d-8520cd038918.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU9N8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1565970-c677-4852-81f4-ced5a4f7e5eb

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC171 | c.2747T>G p.I916S | Missense Mutation (SNP) | VAF 125/2075 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); called by muse, mutect2
- PPP4R3A | c.521T>A p.L174Q | Missense Mutation (SNP) | VAF 64/1874 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RYR3 | c.14205_14216del p.A4737_P4740del (on ENST00000389232; = p.A4738_P4741del on NM_001036.6) | In Frame Del (DEL) | VAF 366/1252 reads (29%) | called by pindel, varscan2
- PAFAH2 | c.768G>A p.V256= | Silent (SNP) | VAF 249/896 reads (28%) | called by muse, mutect2, varscan2
